Gene-level copy-number profile of tumor specimen TCGA-DK-A3IU-01A from TCGA case TCGA-DK-A3IU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 58.5 years (21,369 days).
Specimen TCGA-DK-A3IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.91fbc857-0487-4092-885b-bc2f380d3d0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01042b3a-cc34-430a-a0d0-3aef85ee2a69

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,319; copy number 2: 38,388; copy number 3: 11,253; copy number 4: 2,206; copy number 5: 2,312; copy number 6: 245; copy number 7: 59; copy number 8: 8; copy number 10: 4; copy number 11: 2; copy number 12: 4; copy number 13: 3; copy number 14: 3; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IU-01A-11D-A20B-01): tumor purity 0.27, ploidy 2.48, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:85,112,342–85,238,074, 5 genes: AC114928.1, RBBP4P6, AC117522.3, AC117522.2, AC117522.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,642 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,114,937–50,115,282, 1 gene, copy number 12: AL583843.1.
- chr1:159,276,503–167,937,072, 254 genes, copy number 5–6 (broad region; genes not listed).
- chr2:21,687,430–21,923,288, 2 genes, copy number 5 (within-gene range 2–5): LINC01822, RN7SL117P.
- chr2:56,750,300–56,750,563, 1 gene, copy number 5: PPIAP63.
- chr2:168,915,498–169,031,324, 1 gene, copy number 7 (within-gene range 1–7): ABCB11.
- chr3:101,163,094–101,163,986, 1 gene, copy number 10: ACTR3P3.
- chr3:105,366,909–105,576,900, 1 gene, copy number 6 (within-gene range 2–6): ALCAM.
- chr3:130,345,516–130,484,844, 1 gene, copy number 7 (within-gene range 3–7): COL6A5.
- chr4:10,284,961–10,295,579, 3 genes, copy number 7: AC006499.3, AC006499.5, AC006499.7.
- chr4:29,118,304–29,291,869, 2 genes, copy number 5: AC109349.1, LINC02472.
- chr4:42,892,396–43,030,658, 2 genes, copy number 7 (within-gene range 2–7): RN7SKP82, GRXCR1.
- chr4:46,035,769–46,244,215, 2 genes, copy number 5 (within-gene range 2–5): GABRG1, AC104072.1.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr5:76,075,531–76,084,186, 3 genes, copy number 5: SAP18P1, AC026774.2, AC026774.1.
- chr5:76,091,708–76,091,801, 1 gene, copy number 5: RNA5SP186.
- chr5:114,576,041–114,579,970, 1 gene, copy number 7: LINC01957.
- chr5:125,966,777–125,968,085, 1 gene, copy number 13: RPSAP37.
- chr5:144,856,890–145,228,982, 2 genes, copy number 5 (within-gene range 2–5): AC132803.1, NAMPTP2.
- chr6:5,609,227–21,271,132, 236 genes, copy number 5–6 (broad region; genes not listed).
- chr6:51,385,282–51,385,849, 1 gene, copy number 8: AL158050.2.
- chr7:62,275,361–62,275,678, 1 gene, copy number 10: AC128676.1.
- chr7:126,495,312–126,531,336, 2 genes, copy number 13 (within-gene range 3–13): AC002057.2, AC000374.1.
- chr8:14,022,687–14,023,422, 1 gene, copy number 6: AC023538.1.
- chr8:34,174,886–35,796,550, 9 genes, copy number 5 (within-gene range 3–5): AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1.
- chr8:36,378,069–38,099,931, 38 genes, copy number 7 (within-gene range 3–7): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2.
- chr8:38,122,374–38,122,480, 1 gene, copy number 7: RNU6-988P.
- chr8:43,672,823–43,674,591, 2 genes, copy number 20: AC139365.2, AC139365.1.
- chr8:139,108,430–139,127,953, 2 genes, copy number 14: AC100807.1, AC100807.2.
- chr9:80,563,571–80,565,962, 2 genes, copy number 8: MTCO1P51, MTND2P9.
- chr9:100,975,668–101,325,135, 3 genes, copy number 5 (within-gene range 3–5): GAPDHP26, PLPPR1, AL161631.1.
- chr11:21,383,801–21,383,909, 1 gene, copy number 14: RNA5SP337.
- chr11:50,409,042–54,725,816, 12 genes, copy number 7: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:81,552,226–81,556,425, 2 genes, copy number 10: MTND4LP18, MTND6P25.
- chr11:87,879,473–87,880,095, 1 gene, copy number 12: AP000676.4.
- chr12:15,001,787–15,006,999, 1 gene, copy number 12: LINC01489.
- chr13:18,467,172–48,134,534, 587 genes, copy number 5 (broad region; genes not listed).
- chr13:50,909,747–114,337,626, 742 genes, copy number 5–6 (within-gene range 5–24) (broad region; genes not listed).
- chr14:21,887,857–21,924,651, 5 genes, copy number 8: TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4.
- chr15:53,116,365–53,129,698, 1 gene, copy number 5: LINC02490.
- chr16:76,868,936–76,869,019, 1 gene, copy number 11: MIR4719.

Autosomal genes at a single copy (total copy number 1): 2,898. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
